Somatic mutation profile of tumor specimen TCGA-5M-AATE-01A (aliquot TCGA-5M-AATE-01A-11D-A40P-10) from TCGA case TCGA-5M-AATE, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.3 years (27,870 days).
Specimen TCGA-5M-AATE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08da56b0-b6ed-48c9-9823-85795ecc3200.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5M-AATE-10A (Blood Derived Normal), aliquot TCGA-5M-AATE-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/198e5ef3-1fa4-4677-9191-cd0fd35d9c5a

The open-access MAF lists 145 somatic variants for this specimen: 101 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 39, Nonsense Mutation 6, Frame Shift Ins 2, 3'Flank 1, 3'UTR 1, RNA 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 90/111 reads (81%) | catalogued as rs1211642532, CM994565, COSV57322919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 71/141 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NR5A1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs375469069, CM080459; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 187/415 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 26/37 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52667433, COSV52678360, COSV52751962; called by muse, mutect2, varscan2
- ADAM29 | c.1307C>A p.T436N | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV100821881; called by muse, mutect2, varscan2
- ADCK2 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV99301340; called by muse, mutect2, varscan2
- ADCY8 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs377530734, COSV53920853; called by muse, mutect2, varscan2
- ADGRB2 | c.4297C>T p.R1433C | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs776687412, COSV99925573; called by muse, mutect2, varscan2
- AJAP1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as rs765357051, COSV65450083; called by muse, mutect2, varscan2
- ANKRA2 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.279); catalogued as rs749997797, COSV57142409; called by muse, mutect2, varscan2
- ANXA6 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758088547, COSV62909015; called by muse, mutect2, varscan2
- BCL9 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.099); catalogued as rs368965248; called by muse, mutect2
- BNC2 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101031878, COSV66151404; called by muse, mutect2, varscan2
- CALCR | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 197/266 reads (74%) | catalogued as rs762940513, COSV64006530, COSV64006861; called by muse, mutect2, varscan2
- CFAP54 | c.5330G>A p.R1777K | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs769024966, COSV100732882; called by muse, mutect2, varscan2
- CFAP94 | c.1429G>T p.E477* (on ENST00000320267 / NM_001352064.2; = p.E483* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as rs761067876, COSV57237051; called by muse, mutect2, varscan2
- CLNS1A | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV99627880; called by muse, varscan2
- COL6A1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as rs765826390, COSV62615268; called by muse, mutect2, varscan2
- DDX11 | c.2170G>C p.G724R | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52502163, COSV99298823; called by muse, mutect2, varscan2
- DEAF1 | c.994A>T p.T332S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1215798901, COSV100101664; called by muse, mutect2, varscan2
- DNAH11 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV100176499; called by muse, varscan2
- DNHD1 | c.11275G>A p.E3759K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV99599316; called by muse, mutect2, varscan2
- DPEP1 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV99878249; called by muse, mutect2
- DYSF | c.4757G>A p.R1586Q | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs538781815, COSV99243789; ClinVar: uncertain significance; called by muse, varscan2
- EDIL3 | c.1319A>G p.D440G | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV56888153; called by muse, mutect2
- EYS | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV100675555; called by muse, mutect2
- FCGBP | c.6599C>T p.P2200L | Missense Mutation (SNP) | VAF 58/438 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370331745; called by muse, mutect2, varscan2
- FCRL3 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 107/148 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.427); catalogued as rs373477619; called by muse, mutect2, varscan2
- FZD3 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1229261782, COSV99527764; called by muse, mutect2, varscan2
- GAPVD1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1476937254, COSV52922005, COSV52922883; called by muse, mutect2, varscan2
- GRIA4 | c.1684T>A p.L562I | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99228309; called by muse, mutect2
- GRK3 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as COSV100150955; called by muse, mutect2, varscan2
- H2BW1 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 124/136 reads (91%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs781805108, COSV99474916; called by muse, mutect2, varscan2
- HTR2C | c.1148T>G p.L383W | Missense Mutation (SNP) | VAF 285/321 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99347909; called by muse, mutect2, varscan2
- IGHV4-34 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 63/88 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs3814929; called by muse, mutect2, varscan2
- ING3 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 112/158 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs769542101, COSV59242935; called by muse, mutect2, varscan2
- ITGAD | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV101210297; called by muse, mutect2, varscan2
- KCNQ5 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748981884, COSV100570980; called by muse, mutect2, varscan2
- KIF26A | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs780357438, COSV59467505; called by muse, mutect2, varscan2
- KLHL5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs775525640, COSV54672465; called by muse, mutect2, varscan2
- KRT25 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs557047959, COSV56443537, COSV56444631; called by muse, mutect2, varscan2
- KRT73 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs750485971, COSV59838486; called by muse, mutect2, varscan2
- LAMA2 | c.890C>G p.P297R | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101369859, COSV70346338; called by muse, mutect2, varscan2
- LRRIQ3 | c.951A>C p.K317N | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV63040811; called by muse, mutect2, varscan2
- LZTS3 | c.1433G>A p.R478Q (on ENST00000329152; = p.R432Q on NM_001282533.2) | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV99417246; called by muse, mutect2, varscan2
- MAP4 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV100805353; called by muse, mutect2, varscan2
- MAPK4 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1023559689, COSV68541263; called by muse, mutect2, varscan2
- NECAB1 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101340990; called by muse, mutect2, varscan2
- NOTCH3 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs146578114; called by muse, mutect2, varscan2
- NSMAF | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.274); catalogued as rs773760815, COSV50686257; called by muse, mutect2, varscan2
- OR2Y1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs777452024, COSV57137175; called by muse, mutect2, varscan2
- OR51D1 | c.884T>A p.L295Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100712336; called by muse, mutect2, varscan2
- OR56A3 | c.269G>T p.W90L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV61568452, COSV61570397; called by muse, mutect2, varscan2
- OR8H1 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs935420763, COSV57293024; called by muse, mutect2, varscan2
- PAFAH2 | c.111C>G p.F37L | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100959190; called by muse, mutect2
- PCDHAC1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164923; called by muse, mutect2, varscan2
- PCLO | c.6398C>A p.T2133N | Missense Mutation (SNP) | VAF 131/180 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100426686; called by muse, mutect2, varscan2
- PKD1 | c.5848G>A p.V1950M | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs771669643, COSV99237014; called by muse, mutect2, varscan2
- POM121L12 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs775319102, COSV68692296; called by muse, mutect2, varscan2
- POU4F2 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369337694; called by muse, mutect2, varscan2
- PTH2R | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 95/276 reads (34%) | catalogued as rs756896646, COSV99782012; called by muse, mutect2, varscan2
- PTK2 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 191/381 reads (50%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.782); catalogued as COSV100569256; called by muse, mutect2, varscan2
- PTPRZ1 | c.1207C>G p.Q403E | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101099323; called by muse, mutect2
- RAB3GAP1 | c.2680A>T p.I894F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV99920504; called by muse, mutect2, varscan2
- RABGAP1L | c.1976A>G p.N659S | Missense Mutation (SNP) | VAF 97/147 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs750892098, COSV99267068; called by muse, mutect2, varscan2
- RORB | c.469G>A p.V157I (on ENST00000396204 / NM_001365023.1; = p.V146I on NM_006914.4) | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs975708949, COSV65335600; called by muse, mutect2, varscan2
- RYR1 | c.10295A>C p.E3432A | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV100614207; called by muse, mutect2, varscan2
- SCAF4 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 108/147 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99740734; called by muse, mutect2, varscan2
- SCUBE1 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs746362042, COSV99297631; called by muse, mutect2, varscan2
- SDK1 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1252852069, COSV67358567; called by muse, mutect2, varscan2
- SGCZ | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101166445; called by muse, mutect2, varscan2
- SLC12A3 | c.2432C>T p.A811V (on ENST00000563236 / NM_001126108.2; = p.A820V on NM_000339.3) | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99343741; called by muse, mutect2, varscan2
- SLC7A3 | c.1224C>A p.D408E | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as COSV53229342, COSV99979274; called by muse, mutect2
- SLFN13 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs376142165, COSV99539667; called by muse, mutect2, varscan2
- SNX8 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV99770451; called by muse, mutect2, varscan2
- SOX9 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 11/325 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99818094; called by muse, mutect2
- SPHKAP | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100763620, COSV60883885; called by muse, mutect2
- SPTBN1 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 88/279 reads (32%) | catalogued as COSV100441594; called by muse, mutect2, varscan2
- SYNE2 | c.6685C>G p.L2229V | Missense Mutation (SNP) | VAF 113/161 reads (70%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.943); catalogued as rs375543783; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TAGAP | c.1452C>A p.F484L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as rs1562584291, COSV57851607; called by muse, mutect2, varscan2
- TDRD5 | c.820A>C p.K274Q | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV99675322; called by muse, mutect2, varscan2
- THRAP3 | c.1165A>C p.K389Q | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100663141; called by muse, mutect2, varscan2
- TMEM198 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 111/241 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs1251303878, COSV54727247, COSV54730004; called by muse, mutect2, varscan2
- TMEM74B | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 116/167 reads (69%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV101121953; called by muse, mutect2, varscan2
- TNC | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs967354812, COSV100404794; called by muse, mutect2, varscan2
- TNFSF14 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99838329; called by muse, mutect2, varscan2
- TTN | c.102031C>T p.R34011* (on ENST00000591111; = p.R26587* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 60/121 reads (50%) | catalogued as rs565675340, COSV100591504; called by muse, mutect2, varscan2
- TTN | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 9/105 reads (9%) | PolyPhen probably damaging (0.999); catalogued as rs774434865, COSV100591505; called by muse, mutect2
- TUBB2A | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100373734; called by muse, mutect2, varscan2
- UGT2A1 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99683725; called by muse, mutect2
- UGT2B11 | c.739T>A p.F247I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101485211; called by muse, varscan2
- XPNPEP2 | c.1549A>G p.N517D | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.969); catalogued as COSV100941384; called by muse, mutect2
- ZBED9 | c.2326C>T p.L776F | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV101509081; called by muse, mutect2, varscan2
- ZFAND3 | c.523C>A p.R175S | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99764439; called by muse, mutect2, varscan2
- ZFPM1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs112394415, COSV100128142; called by muse, mutect2, varscan2
- ZNF160 | c.2324G>A p.S775N | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as rs745980290, COSV100762203, COSV100762528; called by muse, mutect2, varscan2
- ZNF443 | c.619T>C p.F207L | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.139); catalogued as COSV100041875; called by muse, mutect2, varscan2
- COPS2 | c.525dup p.H176Tfs*7 | Frame Shift Ins (INS) | VAF 19/156 reads (12%) | called by mutect2, pindel, varscan2
- NBPF9 | c.758A>C p.D253A | Missense Mutation (SNP) | VAF 145/301 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- RNF141 | c.57dup p.V20Sfs*17 | Frame Shift Ins (INS) | VAF 21/140 reads (15%) | called by mutect2, pindel, varscan2
- ACSL4 | c.120C>T p.N40= | Silent (SNP) | VAF 125/137 reads (91%) | catalogued as COSV61614314; called by muse, mutect2, varscan2
- ANK2 | c.3573G>C p.R1191= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99999140; called by muse, mutect2, varscan2
- ANO1 | c.1071C>T p.C357= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs570844488, COSV60283010; called by muse, mutect2, varscan2
- CXorf58 | c.39G>A p.L13= | Silent (SNP) | VAF 272/318 reads (86%) | catalogued as COSV101002915; called by muse, mutect2, varscan2
- DDX10 | c.582C>T p.L194= | Silent (SNP) | VAF 86/218 reads (39%) | catalogued as rs561016413, COSV100488916; called by muse, varscan2
- ECEL1 | c.1179C>T p.P393= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV58811745; called by muse, mutect2, varscan2
- FARP1 | c.2739C>T p.H913= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs148511043, COSV100129430; called by muse, mutect2, varscan2
- GABRB3 | c.168C>T p.F56= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as COSV100157849; called by muse, mutect2
- GLI1 | c.1134G>A p.S378= | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as rs376198615; called by muse, mutect2, varscan2
- INPPL1 | c.1896C>A p.L632= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs1426299825, COSV99995729; called by muse, mutect2, varscan2
- IRGC | c.924C>T p.D308= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs565345774, COSV99746000; called by muse, mutect2, varscan2
- KCNA4 | c.855C>T p.P285= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs759748983, COSV100068847, COSV100069000, COSV60252599; called by muse, mutect2, varscan2
- KCND2 | c.84G>A p.P28= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as rs773004768, COSV58571387; called by muse, mutect2, varscan2
- LGR6 | c.2160C>T p.Y720= (on ENST00000367278 / NM_001017403.1; = p.Y668= on NM_021636.3) | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs3820385; called by muse, mutect2, varscan2
- LRRC7 | c.372C>A p.T124= (on ENST00000651989 / NM_001370785.2; = p.T91= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 93/233 reads (40%) | catalogued as COSV99224068; called by muse, mutect2, varscan2
- MACROD2 | c.945G>A p.V315= (on ENST00000642719; = p.V287= on NM_080676.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 86/124 reads (69%) | catalogued as COSV99425954; called by muse, mutect2, varscan2
- MAST4 | c.7314A>G p.K2438= (on ENST00000403625 / NM_001164664.2; = p.K2249= on NM_015183.3) | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as COSV99842581; called by muse, mutect2, varscan2
- MATN4 | c.417G>A p.P139= | Silent (SNP) | VAF 12/177 reads (7%) | catalogued as rs761046524, COSV100636834; called by muse, mutect2
- METTL24 | c.705C>T p.P235= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as rs752839968, COSV100133105; called by muse, mutect2, varscan2
- MINK1 | c.2247C>T p.S749= | Silent (SNP) | VAF 38/59 reads (64%) | catalogued as rs758507498, COSV100766948; called by muse, mutect2, varscan2
- MTMR7 | c.129C>T p.D43= | Silent (SNP) | VAF 60/109 reads (55%) | catalogued as rs747268193, COSV99471812; called by muse, mutect2, varscan2
- MUC20 | c.1512C>T p.S504= | Silent (SNP) | VAF 40/209 reads (19%) | catalogued as rs769720088, COSV100290859; called by muse, mutect2, varscan2
- NACC2 | c.576G>A p.P192= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1250160451; called by muse, mutect2, varscan2
- NTRK2 | c.624G>A p.V208= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV99451728; called by muse, mutect2, varscan2
- ODF2 | c.1663T>C p.L555= (on ENST00000434106 / NM_153433.2; = p.L531= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100654367; called by muse, mutect2
- OXCT2 | c.912A>G p.R304= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV100560158; called by muse, mutect2, varscan2
- PCDHGB6 | c.1326C>T p.V442= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs1488294674, COSV99529152; called by muse, mutect2, varscan2
- PEG3 | c.2034T>G p.T678= | Silent (SNP) | VAF 11/188 reads (6%) | catalogued as COSV55642079, COSV99690435; called by muse, mutect2
- POGLUT1 | c.978A>G p.Q326= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as rs200054647, COSV99809374; called by muse, mutect2
- SARDH | c.2232C>T p.C744= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as rs934774028, COSV100898279; called by muse, mutect2, varscan2
- SEPHS2 | c.252G>T p.P84= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs764180088, COSV101529297; called by muse, mutect2, varscan2
- SIPA1L3 | c.4632G>A p.S1544= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as rs772885821, COSV99726999; called by muse, mutect2, varscan2
- TBC1D17 | c.1650G>A p.E550= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV99680349; called by muse, mutect2, varscan2
- THAP11 | c.540C>T p.P180= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99534162; called by muse, mutect2, varscan2
- TLL2 | c.969C>T p.G323= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs748603556, COSV63574535; called by muse, mutect2, varscan2
- TNXB | c.3687C>T p.T1229= (on ENST00000647633; = p.T982= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/125 reads (46%) | catalogued as rs369219469; called by muse, mutect2, varscan2
- TRDN | c.375C>T p.D125= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs377440434; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2
- TRPS1 | c.2512C>T p.L838= (on ENST00000220888 / NM_001330599.2; = p.L851= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99627921; called by muse, mutect2, varscan2
- ZNF530 | c.1522C>A p.R508= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV100252361; called by muse, mutect2, varscan2
- COPS9 | chr2:240126584 C>T | 3'Flank (SNP) | VAF 12/106 reads (11%) | catalogued as COSV100216904; called by muse, mutect2, varscan2
- HLA-L | n.944G>A | RNA (SNP) | VAF 36/70 reads (51%) | catalogued as rs747299344; called by muse, mutect2, varscan2
- LARS2 | c.*1049_*1051del | 3'UTR (DEL) | VAF 16/102 reads (16%) | called by pindel, varscan2
- LY6K | c.-86G>A | 5'UTR (SNP) | VAF 20/49 reads (41%) | catalogued as rs1222407174, COSV99456091; called by muse, mutect2, varscan2
- SORCS1 | c.3371+218C>T | Intron (SNP) | VAF 25/58 reads (43%) | catalogued as COSV53872736, COSV99542498; called by muse, mutect2, varscan2
